Surgical pathology report (de-identified scan), TCGA case TCGA-B2-4098, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-B2-4098-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

Left kidney

CLINICAL NOTES

PRE-OP DIAGNOSIS: Renal mass.

GROSS DESCRIPTION

Received fresh for tissue procurement labeled "left kidney" is a 365-gram, 10.5 x 7.5 x 7 cm. left kidney with a moderate amount of attached perirenal adipose tissue. A slightly fragmented 4.8 x 3.4 x 1.5 cm. yellow-orange adrenal gland is present superiorly. A probe-patent 8 cm. ureter averaging 0.3 cm. in diameter is present. On sectioning, there is a 5 x 5 x 4.5 cm. soft congested yellow-orange-brown tumor mass occupying the superior pole. A portion of tumor and a portion of normal are procured as requested. On sectioning, the tumor extends to within 0.5 cm. of the inked surface of the specimen. The tumor appears confined by the renal capsule which is delicate and strips with relative ease from the underlying cortical surface. Immediately adjacent to the tumor are several smooth-lined serous fluid-filled cysts measuring up to 6 cm. The renal pelvis is smooth glistening tan-white. The renal parenchyma is uniform red-brown with a moderately well-defined corticomedullary junction and a maximal cortical thickness of 1.2 cm. Several serous fluid-filled cortical cysts measuring up to 0.9 cm. are evident throughout the specimen. Representative sections are submitted in 11 blocks as labeled. RS-11

BLOCK SUMMARY: 1 - vascular and ureteral margins; 2-4 - tumor to inked surface of specimen; 5-7 - cystic structures adjacent to lesion; 8 - renal pelvis; 9 and 10 - random normal parenchyma; 11 - adrenal gland.

MICROSCOPIC DESCRIPTION

Histologic type: Mixed papillary renal cell carcinoma and clear cell renal cell carcinoma, approximately 50% of each tumor type.
Histologic grade (Fuhrman Nuclear Grade): Both tumor types are grade II
Primary tumor (pT): Tumor measures 5 cm in greatest dimension with no extension beyond the kidney identified (pT1b)
Margins of resection: Negative for tumor
Regional lymph nodes (pN): None identified, pNX
Distant metastasis (pM): Could not evaluate, pMX
Adrenal gland: Negative for tumor
Vascular invasion: Not identified

[page 2 of 2]
[REDACTED]

Non-neoplastic kidney: Chronic interstitial inflammation is present and some benign cysts are present

Other findings: To delineate the two tumor types, CK7, EMA, RCC and

PAX2 immunohistochemical stains were evaluated on tissue block 3 where the two tumor types are both present. The papillary renal cell carcinoma area is very strongly positive for cytokeratin 7 and there is a lack of cytokeratin 7 staining in the clear cell carcinoma area and this helps support the interpretation of the two tumor types being present. The EMA staining is stronger in the papillary area than in the clear cell area. The RCC staining is also somewhat stronger in the papillary area. The PAX2 staining is similar.

4x1, 20x4

[A few of the antibodies used in our laboratory may be classified as

analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

DIAGNOSIS

A. Left kidney, radical nephrectomy:

Renal cell carcinoma, mixed clear cell and papillary type, approximately 50% of each, Fuhrman nuclear grade 2.

Tumor size 5 cm, no extension beyond the kidney is identified (pT1b).

Resection margins are negative for tumor.

Adrenal gland is negative for tumor.

See microscopic description.

[REDACTED]

[REDACTED]

[REDACTED])

Source: NCI Genomic Data Commons file 2e76489c-0ffe-45f7-a855-6e44e39d80a2 (TCGA-B2-4098.9D1802DC-4F4F-47D8-85BB-7E4173143979.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).